Surgical pathology report (de-identified scan), TCGA case TCGA-GV-A3JV, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - Cleveland Clinic, specimen TCGA-GV-A3JV-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code _____

Patient Age/Sex / M

SPECIMEN SUBMITTED:

Part A: RIGHT DISTAL URETER

Part B: LEFT DISTAL URETER

Part C: RIGHT DISTAL URETER #2

Part D: URETHRAL MARGIN

Part E: BLADDER AND PROSTATE

Part F: RIGHT EXTERNAL ILIAC LYMPH
NODES

Part G: RIGHT COMMON ILIAC LYMPH
NODES

Part H: RIGHT OBTURATOR LYMPH
NODES

Part I: RIGHT INTERNAL ILIAC LYMPH
NODES

Part J: LEFT EXTERNAL ILIAC LYMPH
NODES

Part K: LEFT OBTURATOR LYMPH
NODES

Part L: LEFT INTERNAL ILIAC LYMPH
NODES

Part M: LEFT COMMON ILIAC LYMPH
NODES

ICD-0-3

Carcinoma, urothelial, NOS 8120/3

Path Site: bladder, NOS C67.9

CQCF bladder, wall, NOS C67.9

hw
12/15/11

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

Final Diagnosis

1. Right distal ureter, biopsy (A) - Atypical urothelium.
2. Left distal ureter, biopsy (B) - Negative for neoplasm.
3. Right distal ureter #2, biopsy (C) - Ureter, negative for dysplasia.
- Deatched cluster of atypical urothelial cells present of uncertain clinical significance.
4. Urethral margin, biopsy (D) - Negative for neoplasm.
5. Bladder, excision (E) - Invasive poorly differentiated urothelial carcinoma involving bladder and right ureter with extension through bladder wall and involvement of adjacent adipose tissue.
6. Prostate, excision (E) - High-grade prostatic intraepithelial neoplasia.
- Acute and chronic prostatitis.
7. Right external iliac region, biopsy (F) - Benign adipose tissue.
8. Right common iliac lymph nodes, excision (G) - Metastatic urothelial carcinoma involving one of four lymph nodes.
9. Right obturator lymph nodes, excision (H) - Negative for neoplasm, four lymph nodes.
10. Right internal iliac lymph nodes, excision (I) - Negative for neoplasm, four lymph nodes.
11. Left external iliac lymph nodes, excision (J) - Negative for neoplasm, two lymph nodes.
12. Left obturator lymph nodes, excision (K) - Negative for neoplasm, two lymph nodes.
13. Left internal iliac lymph nodes, excision (L) - Benign adipose tissue.
- No lymph node tissue identified.
14. Left common iliac lymph nodes, excision (M) - Negative for neoplasm, one lymph node.
-

[page 3 of 5]
SURGICAL PATHOLOGY REPORT

Diagnosis Comment:

Specimen Type: Radical cystoprostatectomy

Tumor Size, Greatest dimension: 4.5 cm

Histologic Type: Urothelial carcinoma

Urothelial Carcinoma (WHO/ISUP, 1998): High-grade

Adenocarcinoma and Squamous Carcinoma: Not applicable.

Associated Epithelial Lesions: High-grade papillary carcinoma

Margins: See report for parts A through D.

Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Present

Direct Extension of Invasive Tumor: Perivesical fat

Other Diagnoses: See report

Pathologic Stage:

Primary Tumor (pT): pT3b: Macroscopically invades perivesical fat (extravesical mass)

Regional Lymph Nodes (pN): pN1: Metastasis in a single regional lymph node (true pelvis)

Distant Metastasis (pM): pMX: Cannot be assessed

Clinical Diagnosis:

BLADDER CANCER

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

Gross Description:

A. Received fresh for intraoperative consultation labeled "right distal ureter" is a circular segment of red-pink tissue measuring 0.8 x 0.7 x 0.4 cm. The specimen is totally submitted for frozen diagnosis in FSA1.

B. Received fresh for intraoperative consultation is a specimen labeled "left distal ureter" consisting of one segment of circular tan-pink soft tissue measuring 0.4 x 0.2 x 0.2 cm. The specimen is totally submitted for frozen diagnosis in I

C. Received fresh for intraoperative consultation is a specimen labeled "right distal ureter #2" consisting of one segment of circular tan-pink soft tissue measuring 1.5 x 0.3 x 0.3 cm. The specimen is entirely submitted for frozen diagnosis in I

D. Received fresh for intraoperative consultation labeled "urethral margin" are multiple irregular fragments of red-pink soft tissue aggregating to 0.6 x 0.5 x 0.3 cm. The specimen is totally submitted for frozen diagnosis in cassette

[REDACTED]

E. The specimen consists of a urinary bladder, bilateral ureters, prostate and attached seminal vesicles and vas deferens. The bladder measures 12 x 10 x 6.3 cm. The external surface of the bladder is covered by a smooth serosal lining at the dome, and fibroadipose tissue at the remaining portion. This surface is inked black. After the bladder is opened, an area of granular, erythematous mucosa is identified in the trigone region extending around the right ureteral orifice and right bladder wall. This area measures 2.8 x 2.3 cm. No discrete mass is identified on the mucosal surface of the bladder. Upon sectioning, however, there is a mass extending from under the area of erythema around the right ureteral orifice and down along the length of right ureter and into the fat. This mass is tan-white and solid, however, the mid portion of the mass in the right ureter is largely necrotic. The mass measures 4.5 x 3.8 x 2.7 cm in total. The mass appears to extend through the muscularis propria in the portion that involves the bladder wall and into the adipose tissue. It is within 0.7 cm of the inked radial margin at its closest point. The mass does not appear to grossly involve the margin of resection of the right ureter. The right ureter measures 7.2 cm in length. A segment of left ureter is present and measures 2.6 cm in length. Upon opening, the mucosa of the left ureter appears unremarkable. The prostate measures 3.9 cm craniocaudally, 4 cm anteroposteriorly, and 5 cm transversely. The capsular surface is smooth and appears to be intact. The gland is inked blue on the right, and yellow on the left, and sectioned from apex to base transversely at 3 mm intervals perpendicular to the urethra. Cross sections do not reveal a mass lesion. Rubbery nodularity is not present. The seminal vesicles are grossly unremarkable. Representative sections are submitted for permanent evaluation as follows: E1 urethral margin, E2 right ureter margin, E3 left ureter margin, E4 mass with closest radial margin (blue and black ink), E5 mass with right ureter orifice extending into mass, E6 mass and trigone extending through bladder wall, E7 representative section of mass and right bladder wall and right ureter orifice, E8 portion of necrotic mass in mid portion of ureter, E9 additional section of mass and fat, E10 left ureter orifice and trigone, E11 representative section of left wall, E12 representative section of uninvolved right wall, E13 representative section of uninvolved anterior wall, E14 representative section of uninvolved posterior wall, E15 representative section of uninvolved dome, E16 right apex prostate, E17 left apex prostate, E18 right anterior prostate at 6 mm, E19 left anterior prostate at 6 mm, E20 right posterior prostate at 6 mm, E21 left posterior prostate at 6 mm, E22 right anterior prostate at 12 mm, E23 left anterior prostate at 12 mm, E24 right posterior prostate at 12 mm, E25 left posterior prostate at 12 mm, E26 right anterior

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

Gross Description:

prostate at 21 mm, E27 left anterior prostate at 21 mm, E28 right posterior prostate at 21 mm, E29 left posterior prostate at 21 mm.

[REDACTED]

F. Received fresh labeled "right external iliac lymph nodes" are multiple irregular-shaped segments of yellow fibroadipose tissue aggregating to 2.5 x 1.8 x 0.4 cm. Palpation reveals no nodules. The specimen is totally submitted in formalin in one cassette.

G. Received in formalin labeled "right common iliac lymph nodes" are multiple irregular-shaped segments of yellow-tan fibroadipose tissue aggregating to 4.1 x 3.0 x 0.6 cm. Palpation reveals three yellow-tan ovoid firm nodules resembling lymph nodes ranging in size from 0.8 to 1.3 cm. The nodules are totally submitted in formalin in one cassette.

H. Received fresh labeled "right obturator lymph nodes" are multiple irregular-shaped segments of yellow-red fibroadipose tissue aggregating to 4.3 x 2.5 x 0.8 cm. Palpation reveals no nodules. The specimen is totally submitted in formalin in two cassettes.

I. Received fresh labeled "right internal iliac lymph nodes" are multiple irregular-shaped segments of yellow-red fibroadipose tissue aggregating to 5.1 x 4.3 x 1.3 cm. Palpation reveals four yellow-red ovoid firm nodules resembling lymph nodes ranging in size from 0.4 to 2.2 cm. The nodules are totally submitted in formalin as follows: I1 one nodule; I2 one nodule; I3 two nodules.

J. Received fresh labeled "left external iliac lymph nodes" are multiple irregular-shaped segments of yellow-tan fibroadipose tissue aggregating to 4.0 x 2.8 x 1.0 cm. Palpation reveals two yellow-red firm ovoid nodules resembling lymph nodes measuring 1.2 cm and 1.5 cm respectively. The nodules are totally submitted in formalin in one cassette.

K. Received fresh labeled "left obturator lymph nodes" are multiple irregular-shaped segments of yellow-red fibroadipose tissue aggregating to 4.5 x 2.8 x 0.8 cm. Palpation reveals no nodules. The specimen is totally submitted in two cassettes.

L. Received fresh labeled "left internal iliac lymph nodes" are multiple irregular-shaped segments of yellow-red fibroadipose tissue aggregating to 2.3 x 2.3 x 0.3 cm. Palpation reveals no nodules. The specimen is totally submitted in formalin in one cassette.

M. Received fresh labeled "left common iliac lymph nodes" are multiple irregular-shaped segments of yellow-tan fibroadipose tissue aggregating to 2.8 x 2.0 x 0.6 cm. Palpation reveals one yellow-tan ovoid firm nodule resembling a lymph node measuring 1.3 cm in greatest dimension. The nodule is totally submitted in formalin in one cassette.

[REDACTED]

Source: NCI Genomic Data Commons file 98cc9a37-c577-428c-9dd7-d3983ded7e18 (TCGA-GV-A3JV.098BAA98-ACDF-4E3B-9383-03ECFB214CB3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).